Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4799, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4799-01A (Primary Tumor).

[page 1 of 3]
TCGA-BP-4799

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

Renal cell carcinoma.

Specimens Submitted:

1: SP: Right kidney and adrenal gland, radical nephrectomy

2: SP: Lymph nodes, retrocaval, excision

DIAGNOSIS:

1. SP: Right kidney and adrenal gland, radical nephrectomy:

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade III/IV

Tumor Size:

Greatest diameter is 6.0 cm.

Local Invasion (for renal cortical types):

Extends through renal capsule but confined within Gerota's fascia

Involves renal sinus fat

Renal Vein Invasion:

Not identified

However, muscular branches of renal vein in the hilum are invaded by the tumor

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Mild arteriosclerotic changes, benign cortical cysts, perirenal organizing hemorrhage

Adrenal Gland:

Not involved

Multiple foci of cortical amyloidosis (congo red positive); vessels and soft tissues not involved by amyloidosis.

Stains to characterize the amyloid deposits are being performed, and results on these will be reported as an addendum.

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT3b Tumor grossly extends into the renal vein(s) or vena cava below the diaphragm

[page 2 of 3]
2. Lymph nodes, retrocaval, excision:

Malignant lymphoma, marginal zone type (see note)

- Immunostains show that most lymphocytes are positive for CD20, BCL-2, and CD43, while negative for CD3, Cyclin D1, CD5, CD10, and CD23. Rare cells are positive for BCL-6. MIB-1 staining shows a proliferation rate of approximately 5%.
- No evidence of amyloid deposition is seen.
- No metastatic carcinoma is identified.

Benign adrenal tissue with focal amyloid deposits.

Note: Review of the original core biopsy [REDACTED] shows a malignant lymphoma with morphologic and immunohistochemical features similar to the present material, and consistent with a marginal zone lymphoma.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:

Result	Special Stain	Comment
	CONGO RED	
	CD3 (Leu4)	
	CD20 L26	
	CD138	
	K	
	L	
	CONGO RED	
	CONGO RED	
	NEG CONT	
	IMM RECUT	
	RECUT	
	CD3 (Leu4)	
	CD5	
	CD10	
	CD20 L26	
	CD23	
	CD43 Leu22	
	BCL2	
	BCL6	
	CYD1	
	MIB-1	
	NEG CONT	
	IMM RECUT	

Gross Description:

1) The specimen is received fresh labeled "right kidney and adrenal gland" and consists of a kidney with attached ureter, renal vessels and perinephric fat weighing 1783 g in total. The kidney measures 28 x 12 x 11.5 cm. The attached ureter measures 2.0 cm in length and 1.0 cm in diameter. The attached renal vein measures .4 cm in length and 0.6 cm in diameter. The renal vessels and ureter margins are grossly unremarkable. An adrenal gland is identified. The kidney is inked black and bisected to reveal large a hematoma along the lateral aspect of the kidney measuring up to 17 cm. A multiloculated mass with variegated yellow to hemorrhagic cut-surface is identified in the mid portion of the kidney, approaching the hilum, and measuring 6.0 x 4.2 x 2.5 cm. Most of the remaining kidney is tan and fibrotic. The corticomedullary junction is indistinct. Few clear-fluid-filled thin-walled cysts are present in the cortex. The calices are filled with blood. No lymph nodes are identified in the perinephric fat. Representative sections are submitted for TPS and for permanent sections. Photographs are taken.

Summary of sections:

A - adrenal gland

UVM -- ureteral and vessel margins

[page 3 of 3]
T-- tumor
THF-- tumor with hilar fat
TSF -- tumor with sinus fat and spleen
TK -- tumor with adjacent kidney
RP -- renal pelvis representative sections
K -- representative sections kidney

2). The specimen is received in formalin, labeled "retrocaval lymph nodes" and consists of two pink tan firm lymph nodes measuring to 3.0 and 4.0 cm in greatest dimension respectively. All identified lymph nodes are submitted.

Summary of sections:

LN1 -- lymph node number one

LN2 -- lymph node number two

Summary of Sections:

Part 1: SP: Right kidney and adrenal gland, radical nephrectomy

Block	Sect. Site	PCs
1	a	1
2	adda	2
3	k	3
1	rp	1
8	t	8
1	thf	1
2	tk	2
3	tsf	3
1	uvm	1

Part 2: SP: Lymph nodes, retrocaval, excision

Block	Sect. Site	PCs
4	ln1	4
6	ln2	6

Procedures/Addenda:

Addendum

Addendum Diagnosis

Immunostains for kappa and lambda show non-specific staining, without association with lymphocytes or plasma cells. Congo-red stain performed on sections from non-neoplastic renal parenchyma do not reveal any amyloidosis in the kidney.

Source: NCI Genomic Data Commons file 1e15405c-6383-4e20-869b-fd3bf265c93c (TCGA-BP-4799.A2274142-6192-4C56-B29A-31A7B05A3320.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).